Somatic mutation profile of tumor specimen TCGA-LN-A49L-01A (aliquot TCGA-LN-A49L-01A-11D-A247-09) from TCGA case TCGA-LN-A49L, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 44.3 years (16,164 days).
Specimen TCGA-LN-A49L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) acb0da86-2ba8-473c-8544-73d7ce9e27f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A49L-10A (Blood Derived Normal), aliquot TCGA-LN-A49L-10A-01D-A247-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54a56c47-3aba-4843-9e2f-d4ed93b1aeee

The open-access MAF lists 169 somatic variants for this specimen: 134 protein-altering or splice-affecting, 30 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 112, Silent 30, Nonsense Mutation 12, Frame Shift Del 4, 3'UTR 3, Splice Site 3, In Frame Ins 1, Frame Shift Ins 1, In Frame Del 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD8 | c.187G>T p.A63S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.001); catalogued as COSV53112506; called by muse, mutect2
- ALK | c.841C>A p.H281N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.346); catalogued as COSV66574313, COSV66578531; called by muse, mutect2, varscan2
- ASIC4 | c.755G>C p.R252P | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV100761828; called by muse, mutect2, varscan2
- BAZ2A | c.4628C>T p.P1543L | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as rs1392230769; called by muse, mutect2, varscan2
- C10orf53 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); catalogued as COSV65108587; called by muse, mutect2, varscan2
- C20orf27 | c.475G>T p.A159S (on ENST00000379772 / NM_001258429.2; = p.A184S on NM_001039140.3) | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.233); catalogued as COSV53923679; called by muse, varscan2
- CHAT | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1306112783, CM105868, COSV60321866, COSV60328063; called by muse, mutect2, varscan2
- CNTN6 | c.691G>C p.V231L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.332); catalogued as rs373831062; called by muse, mutect2, varscan2
- CSPG4 | c.3040G>A p.V1014M | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs925306142, COSV100413882, COSV57893036; called by muse, mutect2, varscan2
- DPP10 | c.1114-1G>T p.X372_splice | Splice Site (SNP) | VAF 10/36 reads (28%) | catalogued as COSV59677764; called by muse, mutect2, varscan2
- EPHA8 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1351802924, COSV51262954; called by muse, mutect2, varscan2
- FOXD4L5 | c.838G>A p.G280R | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs781582393, COSV101073104, COSV66241318; called by mutect2, varscan2
- GRIK4 | c.1420G>C p.G474R | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101483753; called by muse, mutect2, varscan2
- GRK7 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs777683287; called by muse, mutect2, varscan2
- HTRA1 | c.1351G>A p.V451I | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs149822364; called by muse, mutect2, varscan2
- IGKV1D-43 | c.59C>A p.A20D | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as rs368187966; called by muse, mutect2, varscan2
- KRT2 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1049427619; called by muse, mutect2, varscan2
- KRT73 | c.617C>G p.S206W | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59838457; called by muse, mutect2, varscan2
- MAF1 | c.194C>A p.S65* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as COSV59364104; called by muse, mutect2, varscan2
- MCC | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.964); catalogued as rs765539734, COSV56738733; called by muse, mutect2, varscan2
- MICALL1 | c.2449G>T p.E817* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV53239215; called by mutect2, varscan2
- NEK1 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as rs781184197; called by muse, varscan2
- NFKBIZ | c.1904T>G p.L635R | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs1043339; called by muse, mutect2, varscan2
- NLRP13 | c.1111C>A p.L371I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV61622030; called by muse, mutect2, varscan2
- NR2E3 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as COSV58907006, COSV58907828; called by muse, mutect2
- NRDE2 | c.835A>G p.T279A | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs761651321; called by muse, mutect2, varscan2
- NRXN2 | c.2002C>T p.R668* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as rs770105914, COSV99634989; called by muse, varscan2
- PARPBP | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as rs753543416; called by muse, mutect2, varscan2
- PCBP3 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1240869164; called by muse, mutect2, varscan2
- PCDH10 | c.2257G>A p.A753T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.018); catalogued as rs1464822930; called by muse, mutect2, varscan2
- PIGK | c.909C>A p.F303L | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV63063974; called by muse, mutect2, varscan2
- PPP4R4 | c.1558G>C p.D520H | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58554549; called by muse, mutect2, varscan2
- PRRC2B | c.1951C>T p.P651S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.796); catalogued as COSV61937198; called by mutect2, varscan2
- PWWP3B | c.1201C>G p.Q401E | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV61798626; called by muse, mutect2, varscan2
- RTN1 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV50718619; called by muse, mutect2, varscan2
- RYR2 | c.3769C>T p.Q1257* | Nonsense Mutation (SNP) | VAF 11/89 reads (12%) | catalogued as COSV63698700; called by muse, mutect2, varscan2
- SUGP2 | c.2027C>T p.P676L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs372273190; called by muse, mutect2
- TAFA4 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55134261; called by muse, mutect2, varscan2
- TP53 | c.383del p.P128Lfs*42 | Frame Shift Del (DEL) | VAF 7/18 reads (39%) | catalogued as COSV53283607; called by mutect2, pindel, varscan2
- TUBA3D | c.728G>T p.R243L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV58311623; called by muse, mutect2, varscan2
- UBE3C | c.1708G>C p.E570Q | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.854); catalogued as COSV61955748; called by muse, mutect2, varscan2
- ZNF653 | c.1129A>G p.T377A | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV53402707; called by muse, mutect2
- ADAM29 | c.1644T>A p.D548E | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AK5 | c.1094C>G p.T365S (on ENST00000354567 / NM_174858.3; = p.T339S on NM_012093.4) | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALDH1L1 | c.2507C>T p.S836F | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANK1 | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AP2B1 | c.2648G>T p.G883V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- APLP1 | c.1523G>T p.G508V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- ARGLU1 | c.447G>T p.R149S | Missense Mutation (SNP) | VAF 61/126 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ARHGAP35 | c.4227C>A p.F1409L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ARHGEF18 | c.1500_1501del p.E501Sfs*22 (on ENST00000359920 / NM_001130955.2; = p.E397Sfs*22 on NM_015318.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- ATP10D | c.3772G>T p.V1258F | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- BICDL2 | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- BOD1L1 | c.6768C>G p.I2256M | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- C17orf50 | c.429G>C p.K143N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- CCDC58 | c.320C>A p.T107K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- CD34 | c.559C>G p.Q187E | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.058); called by muse, mutect2
- CFAP100 | c.649G>T p.A217S | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CFL1 | c.4-2A>T p.X2_splice | Splice Site (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- CHKB | c.868C>A p.H290N | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.527); called by muse, mutect2
- CLN6 | c.427C>A p.Q143K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- COPS5 | c.616A>G p.I206V | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- CPSF1 | c.1373T>C p.L458P | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CRIP3 | c.343A>C p.K115Q | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.134); called by muse, mutect2
- CUBN | c.49A>G p.I17V | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DCLRE1C | c.1532C>A p.T511K (on ENST00000378278 / NM_001350965.2; = p.T396K on NM_022487.4) | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DCLRE1C | c.1531A>C p.T511P (on ENST00000378278 / NM_001350965.2; = p.T396P on NM_022487.4) | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- DNAH2 | c.9808G>A p.E3270K | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- DPP6 | c.1904A>T p.Q635L (on ENST00000377770 / NM_001364500.2; = p.Q573L on NM_001936.5) | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- DST | c.8599G>A p.G2867S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- DST | c.6461T>G p.I2154R | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYNC1I1 | c.366-1G>A p.X122_splice | Splice Site (SNP) | VAF 55/126 reads (44%) | called by muse, mutect2, varscan2
- EDC3 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.419); called by muse, mutect2
- EMC1 | c.1680T>A p.Y560* | Nonsense Mutation (SNP) | VAF 15/66 reads (23%) | called by muse, mutect2, varscan2
- FAM111A | c.1468C>T p.Q490* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2, varscan2
- FANCF | c.326A>G p.Y109C | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- FNDC3A | c.86A>G p.D29G | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- FZD7 | c.1318_1323dup p.L440_L441dup | In Frame Ins (INS) | VAF 53/67 reads (79%) | called by mutect2, pindel, varscan2
- GSE1 | c.809C>A p.S270Y | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- HEATR1 | c.1555A>G p.K519E | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- HEPH | c.1064A>T p.D355V (on ENST00000343002; = p.D88V on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- HSD3B7 | c.1006G>T p.D336Y | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- ICAM2 | c.313A>C p.N105H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- IFT172 | c.5021T>C p.L1674P | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KALRN | c.3547C>A p.Q1183K | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- KIT | c.1770T>G p.S590R | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (1); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- KLHL6 | c.249C>A p.F83L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAPK6 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- MARCHF10 | c.192C>A p.S64R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- MOB4 | c.127A>G p.I43V | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NAE1 | c.968T>G p.L323* | Nonsense Mutation (SNP) | VAF 29/53 reads (55%) | called by muse, mutect2, varscan2
- NALCN | c.1210A>G p.N404D | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- NARF | c.732G>T p.L244F | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- NPAT | c.3973G>C p.E1325Q | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR1L6 | c.306C>A p.N102K (on ENST00000373684; = p.N66K on NM_001004453.2) | Missense Mutation (SNP) | VAF 43/67 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- OR9G1 | c.463T>C p.S155P | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2
- PRAMEF17 | c.116T>C p.M39T | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- PRKCB | c.795A>T p.E265D | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- PRKG2 | c.1963C>A p.Q655K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- PROM1 | c.1175A>G p.D392G | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- PRTN3 | c.442del p.H148Tfs*60 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | called by mutect2, pindel, varscan2
- PSAP | c.682G>C p.E228Q | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- PSMD8 | c.336C>G p.C112W | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RAB3GAP2 | c.197C>G p.T66S | Missense Mutation (SNP) | VAF 73/131 reads (56%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- RFTN1 | c.1165G>T p.D389Y | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCCPDH | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.29); called by muse, mutect2
- SGO1 | c.484C>G p.P162A | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, mutect2
- SI | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC3A2 | c.3_25del p.M1_?9 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- SLC6A5 | c.362A>G p.K121R | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNAPC4 | c.855G>T p.Q285H | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPATA31D1 | c.3017C>A p.S1006Y | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- SUSD1 | c.1898C>G p.S633C | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- SYNRG | c.1234T>A p.S412T | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TANGO6 | c.2837C>A p.A946E | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TAS1R3 | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- TMEM129 | c.388dup p.L130Pfs*19 | Frame Shift Ins (INS) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- TMEM150A | c.312G>C p.Q104H (on ENST00000334462 / NM_001031738.3; = p.Q51H on NM_153342.3) | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- TMEM155 | c.257G>T p.S86I | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- TMEM45A | c.736T>G p.L246V | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TNFAIP6 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAM1L1 | c.96_113del p.M32_L38delinsI | In Frame Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- USP34 | c.6730G>T p.E2244* | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- USP47 | c.2135G>A p.G712E (on ENST00000399455 / NM_001372095.1; = p.G624E on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.189); called by muse, mutect2
- VDR | c.1204C>G p.R402G | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- WDFY3 | c.3520G>T p.E1174* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2, varscan2
- WRN | c.3791C>G p.S1264C | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- WSCD1 | c.1260G>A p.M420I | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.38); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- XRN1 | c.1668A>T p.K556N | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZMYM1 | c.2729A>C p.K910T | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF570 | c.1414T>C p.C472R | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF749 | c.1294C>A p.H432N | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ZNF880 | c.874G>T p.G292* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- ZSWIM1 | c.453C>A p.F151L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- ABHD8 | c.597G>C p.V199= | Silent (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
- AHRR | c.1011A>G p.E337= | Silent (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- ANK2 | c.10017G>A p.A3339= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs774143296, COSV52154986; ClinVar: likely benign; called by mutect2, varscan2
- CAPRIN2 | c.2136A>T p.S712= | Silent (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- COG4 | c.597C>G p.L199= | Silent (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- CSMD2 | c.5493C>T p.G1831= | Silent (SNP) | VAF 21/34 reads (62%) | catalogued as rs189437127; called by muse, mutect2, varscan2
- DDIT4 | c.612C>T p.F204= | Silent (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- ELAPOR2 | c.984C>T p.D328= (on ENST00000450689 / NM_001142749.3; = p.D161= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs774408868, COSV51890019, COSV51890104; called by muse, mutect2, varscan2
- ESRRG | c.594G>C p.V198= | Silent (SNP) | VAF 10/96 reads (10%) | called by muse, mutect2
- FIBP | c.606C>T p.C202= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs764460613; called by muse, mutect2, varscan2
- GGN | c.1164C>A p.G388= | Silent (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- JAM3 | c.441G>A p.P147= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs371009569; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAP1LC3A | c.105C>T p.I35= | Silent (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2
- NLRP13 | c.2568G>A p.K856= | Silent (SNP) | VAF 49/51 reads (96%) | catalogued as rs1301361814; called by muse, mutect2, varscan2
- OPTN | c.162G>A p.L54= | Silent (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2
- OR4C16 | c.382C>T p.L128= | Silent (SNP) | VAF 37/56 reads (66%) | catalogued as rs756023612, COSV58944701; called by muse, mutect2, varscan2
- PHIP | c.4647G>A p.V1549= | Silent (SNP) | VAF 11/45 reads (24%) | called by muse, mutect2, varscan2
- PI4KA | c.6105C>G p.V2035= | Silent (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- POU2F1 | c.516C>T p.I172= (on ENST00000541643 / NM_001365848.1; = p.I195= on NM_002697.4) | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs562014026, COSV99611314; called by muse, mutect2, varscan2
- PPP1R26 | c.1134G>A p.Q378= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs1324661601; called by muse, mutect2, varscan2
- PPP3CC | c.642T>C p.F214= | Silent (SNP) | VAF 31/93 reads (33%) | called by muse, mutect2, varscan2
- RASGRP4 | c.1248C>T p.F416= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as rs753112169; called by muse, mutect2, varscan2
- ROBO3 | c.1689G>C p.V563= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs1259844373; called by muse, mutect2, varscan2
- SCYL2 | c.84C>A p.V28= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV62567885; called by muse, mutect2, varscan2
- SEC14L2 | c.891C>T p.L297= | Silent (SNP) | VAF 31/42 reads (74%) | catalogued as rs1169409129, COSV57241218; called by muse, mutect2, varscan2
- SV2B | c.1731A>C p.A577= | Silent (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
- TRPM7 | c.2091C>T p.S697= | Silent (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- ZC3H4 | c.1959G>A p.P653= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as rs746699853, COSV99453035; called by muse, mutect2, varscan2
- ZKSCAN3 | c.285G>T p.L95= | Silent (SNP) | VAF 24/59 reads (41%) | called by muse, mutect2, varscan2
- ZNF268 | c.588A>T p.S196= | Silent (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- DNAJC11 | c.*1003G>A | 3'UTR (SNP) | VAF 13/39 reads (33%) | catalogued as rs1211448689, COSV50011138; called by muse, mutect2, varscan2
- GP6 | c.*4C>T | 3'UTR (SNP) | VAF 37/50 reads (74%) | called by muse, mutect2, varscan2
- GP6 | c.*3G>T | 3'UTR (SNP) | VAF 38/51 reads (75%) | catalogued as rs759751882; called by muse, mutect2, varscan2
- IGHV1-12 | n.187G>T | RNA (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2, varscan2
- VKORC1 | chr16:31095424 C>T | 5'Flank (SNP) | VAF 10/32 reads (31%) | catalogued as rs1248676894; called by muse, mutect2, varscan2
